Somatic mutation profile of cancer-model specimen HCM-BROD-0335-C43-85M (Adherent Cell Line, passage 14; aliquot HCM-BROD-0335-C43-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0335-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.7 years (22,537 days).
Specimen HCM-BROD-0335-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d4ed60e-c720-4b99-a48c-b7947520d933.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0335-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0335-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1156065b-04ed-4ab3-b4ea-09ba17567bd9

The open-access MAF lists 620 somatic variants for this specimen: 354 protein-altering or splice-affecting, 183 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 321, Silent 183, Intron 45, Nonsense Mutation 23, RNA 17, 3'UTR 10, 5'UTR 7, Splice Site 4, 5'Flank 3, In Frame Del 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 636/788 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LDLR | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879254898, CM055366, COSV52941516; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV65311401; called by muse, mutect2, varscan2
- ABI3BP | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 136/204 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52528711; called by muse, mutect2, varscan2
- ABL1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 205/205 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764838466; called by muse, mutect2, varscan2
- AC092143.1 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 158/310 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100206043; called by muse, mutect2, varscan2
- ACO2 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 113/250 reads (45%) | catalogued as COSV53445398; called by muse, mutect2, varscan2
- ADAMTS9 | c.4253C>T p.P1418L | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV55780965; called by muse, mutect2, varscan2
- ADCY1 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99812102; called by muse, mutect2, varscan2
- ADCY8 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 206/374 reads (55%) | catalogued as COSV53896968; called by muse, mutect2, varscan2
- AFAP1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 54/209 reads (26%) | catalogued as COSV61795539; called by muse, mutect2, varscan2
- AFM | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs766338035, COSV56920226; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 300/301 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AHNAK2 | c.16286C>T p.P5429L | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.375); catalogued as rs752919542; called by muse, mutect2, varscan2
- AHNAK2 | c.9752C>T p.P3251L | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375163419; called by muse, mutect2, varscan2
- ALKBH4 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 306/364 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs544559313; called by muse, mutect2, varscan2
- AMBN | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146171297, COSV59826079; called by muse, mutect2, varscan2
- APC2 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs1438690403; called by muse, mutect2, varscan2
- APLNR | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs767481092, COSV57241337; called by muse, mutect2, varscan2
- ARHGAP5 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs750575178, COSV61539117; called by muse, mutect2, varscan2
- ARID4B | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1398553805; called by muse, mutect2, varscan2
- ASXL3 | c.3653C>T p.S1218L | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs780764559, COSV52455959; called by muse, mutect2, varscan2
- ATP1B4 | c.604C>T p.P202S (on ENST00000218008 / NM_001142447.3; = p.P198S on NM_012069.5) | Missense Mutation (SNP) | VAF 86/86 reads (100%) | SIFT tolerated (0.81); PolyPhen benign (0.277); catalogued as COSV99486417; called by muse, mutect2, varscan2
- B4GALNT2 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 119/433 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489404226, COSV55928231; called by muse, mutect2, varscan2
- CACNA1E | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 80/258 reads (31%) | catalogued as rs1484841139, COSV62437802; called by muse, mutect2, varscan2
- CCDC63 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1221505795, COSV57527710, COSV57530943; called by muse, mutect2, varscan2
- CDC14C | c.1489G>A p.D497N (on ENST00000428251; = p.D390N on NM_152627.3) | Missense Mutation (SNP) | VAF 181/858 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs765363567; called by muse, mutect2, varscan2
- CDH7 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 187/307 reads (61%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.67); catalogued as rs747158201; called by muse, mutect2, varscan2
- CEACAM18 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 148/493 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs752008606; called by muse, mutect2, varscan2
- CEACAM21 | c.784C>T p.R262* (on ENST00000401445 / NM_001098506.4; = p.R261* on NM_033543.6) | Nonsense Mutation (SNP) | VAF 104/319 reads (33%) | catalogued as rs568421412, COSV51816111; called by muse, mutect2, varscan2
- CECR2 | c.2263C>T p.P755S (on ENST00000342247 / NM_001290047.2; = p.P572S on NM_001290046.1) | Missense Mutation (SNP) | VAF 147/313 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52843387; called by muse, mutect2, varscan2
- CFAP100 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs779910097; called by muse, mutect2, varscan2
- CFHR3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100807594, COSV66403215; called by muse, mutect2, varscan2
- CHMP1A | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs774284263; called by muse, mutect2, varscan2
- CLCN1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 131/742 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749902453, COSV58369696; called by muse, mutect2, varscan2
- CNMD | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 121/196 reads (62%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV100937237, COSV65034217; called by muse, mutect2, varscan2
- CNTN5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 94/182 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs200579368, COSV54326826; called by muse, mutect2, varscan2
- COL11A2 | c.2687C>T p.P896L (on ENST00000341947 / NM_080680.3; = p.P789L on NM_080679.2) | Missense Mutation (SNP) | VAF 382/787 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs150065075; called by muse, mutect2, varscan2
- COL5A2 | c.2816G>A p.G939E | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200605931; called by muse, mutect2, varscan2
- CRAMP1 | c.3620C>T p.S1207F | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51963945, COSV99245480; called by muse, mutect2, varscan2
- CRISP3 | c.557C>T p.A186V (on ENST00000371159 / NM_001368123.1; = p.A168V on NM_006061.4) | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs775443908; called by muse, mutect2, varscan2
- CYP4F22 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs140968002; called by muse, mutect2, varscan2
- CYP4X1 | c.1260G>A p.W420* | Nonsense Mutation (SNP) | VAF 70/139 reads (50%) | catalogued as COSV64150455; called by muse, mutect2, varscan2
- DCAF6 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56584097; called by muse, mutect2, varscan2
- DMRT3 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 193/194 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as rs537931256; called by muse, mutect2, varscan2
- DNAH9 | c.10877G>A p.R3626H | Missense Mutation (SNP) | VAF 142/143 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as rs183636309; called by muse, mutect2, varscan2
- DNAJB7 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1463861502, COSV53421743; called by muse, mutect2, varscan2
- DNAJB8 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 142/233 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs778186479, COSV59878117; called by muse, mutect2, varscan2
- DOP1B | c.5743C>T p.R1915* | Nonsense Mutation (SNP) | VAF 209/309 reads (68%) | catalogued as rs778603259, COSV101215716; called by muse, mutect2, varscan2
- DST | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs767667427, COSV56812271; called by muse, mutect2, varscan2
- EFL1 | c.1613T>C p.V538A | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs754585196; called by muse, varscan2
- EXPH5 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99761056; called by muse, mutect2, varscan2
- FAM3B | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 327/518 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016055826; called by muse, mutect2, varscan2
- FAT4 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs781223192, COSV67897063; called by muse, mutect2, varscan2
- FBXO24 | c.56C>T p.P19L (on ENST00000241071 / NM_033506.3; = p.P57L on NM_012172.5) | Missense Mutation (SNP) | VAF 152/179 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV53825322; called by muse, mutect2, varscan2
- FMO4 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 156/759 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100882063; called by muse, mutect2, varscan2
- FOXD3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs1489615376; called by muse, mutect2, varscan2
- GABRE | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GABRR3 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs1156273819; called by muse, mutect2
- GIMAP6 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV100188062, COSV61033781; called by muse, mutect2, varscan2
- GLP2R | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs753108361; called by muse, mutect2, varscan2
- GP6 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 137/215 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV59976740; called by muse, mutect2, varscan2
- GPR65 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs746098918, COSV50862766; called by muse, mutect2, varscan2
- GRIP1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 313/314 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54032350; called by muse, mutect2, varscan2
- H1-6 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 165/381 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1384996067, COSV58091036; called by muse, mutect2, varscan2
- HHLA1 | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 93/768 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1461249333; called by muse, mutect2, varscan2
- HMCN2 | c.11128G>A p.D3710N | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs780196691; called by muse, mutect2, varscan2
- HNRNPD | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV58312699; called by muse, mutect2, varscan2
- HSD17B2 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV52277770; called by muse, mutect2, varscan2
- HSPB7 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.4); catalogued as rs1355982472; called by muse, mutect2, varscan2
- HTR4 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 282/283 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779822851, COSV58789696; called by muse, mutect2, varscan2
- IGHD3-9 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 62/126 reads (49%) | catalogued as rs782434392; called by muse, mutect2, varscan2
- INF2 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs1314746427, COSV53032023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ISL1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs759969078, COSV57932855, COSV57932880; called by muse, mutect2, varscan2
- ITGAX | c.3347G>A p.G1116D | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1248924690, COSV51648766, COSV99191846; called by muse, mutect2, varscan2
- KRTAP10-8 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 498/729 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs782225914; called by muse, mutect2, varscan2
- KRTAP4-6 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 394/396 reads (99%) | SIFT deleterious (0.03); catalogued as rs748116984; called by mutect2, varscan2
- KY | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 63/224 reads (28%) | catalogued as rs373240849, COSV101415008; called by muse, mutect2, varscan2
- LGALS14 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs866404052, COSV62373089; called by muse, mutect2, varscan2
- LITAF | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 168/362 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1247099563; called by muse, mutect2, varscan2
- LMX1A | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 124/172 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs759331204, COSV54218097, COSV54227124; called by muse, mutect2
- LRP1B | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs150366199, COSV67200606; called by muse, mutect2, varscan2
- LRRC55 | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV73006419; called by muse, mutect2, varscan2
- LSP1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as rs755491188, COSV61137239; called by muse, mutect2, varscan2
- MAGEC2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 130/131 reads (99%) | SIFT tolerated (0.23); PolyPhen benign (0.424); catalogued as COSV55998321, COSV56002040; called by muse, mutect2, varscan2
- MAP1S | c.2548C>A p.P850T | Missense Mutation (SNP) | VAF 110/156 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV60721688; called by muse, mutect2
- MECOM | c.1877C>T p.S626F (on ENST00000468789 / NM_001105078.4; = p.S814F on NM_004991.4) | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52959070, COSV52960579; called by muse, mutect2, varscan2
- MGAM | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 139/799 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374506553; called by muse, mutect2, varscan2
- MGAM | c.5107C>T p.P1703S | Missense Mutation (SNP) | VAF 473/658 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV72075771; called by muse, mutect2, varscan2
- MMP3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55404953; called by muse, mutect2, varscan2
- MPP4 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 123/123 reads (100%) | catalogued as rs369650968; called by muse, mutect2, varscan2
- MRGPRD | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV58423779, COSV58423856; called by muse, mutect2
- MTUS2 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216056781, COSV54987399; called by muse, mutect2, varscan2
- MUC17 | c.5009C>T p.S1670L | Missense Mutation (SNP) | VAF 106/524 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs145566218, COSV60286645; called by muse, mutect2, varscan2
- MUC4 | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV62130849; called by muse, mutect2, varscan2
- MUC4 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 261/397 reads (66%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.65); catalogued as rs754489958; called by muse, mutect2, varscan2
- MYH7 | c.4975G>A p.D1659N | Missense Mutation (SNP) | VAF 236/522 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs267603953; called by muse, mutect2, varscan2
- MYLK | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 287/886 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as rs773956836, COSV60606435; ClinVar: likely benign; called by muse, mutect2, varscan2
- NKX2-3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs774453161; called by muse, mutect2
- NLRP4 | c.2105C>T p.T702I | Missense Mutation (SNP) | VAF 133/198 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs967849267; called by muse, mutect2, varscan2
- NRXN3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 112/202 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV101627037; called by muse, mutect2, varscan2
- NYAP2 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV56013260, COSV99798673; called by muse, mutect2
- ONECUT2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs954601926, COSV72152977; called by muse, mutect2, varscan2
- OR14K1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs1472766835; called by muse, mutect2, varscan2
- OR1N2 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1243131027, COSV65460512; called by muse, mutect2, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- OR51G2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.949); catalogued as rs1443879322; called by muse, mutect2, varscan2
- OR52A1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 148/307 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs753102211, COSV61092141, COSV61093171; called by muse, mutect2, varscan2
- OR52J3 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs773085013, COSV66747281; called by muse, mutect2, varscan2
- PAK5 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416163895, COSV62026355, COSV62029552; called by muse, mutect2, varscan2
- PAX7 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 132/256 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV64749033, COSV64751600; called by muse, mutect2, varscan2
- PCDH12 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 281/282 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756909340; called by muse, mutect2, varscan2
- PCDHA11 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 228/228 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.309); catalogued as COSV56484245; called by muse, mutect2, varscan2
- PCDHA12 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as COSV56475281; called by muse, mutect2
- PCDHGA10 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as rs1418394305; called by muse, mutect2, varscan2
- PCDHGA3 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 360/410 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs757402197; called by muse, mutect2, varscan2
- PCLO | c.13813C>T p.H4605Y | Missense Mutation (SNP) | VAF 336/407 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61655973; called by muse, mutect2, varscan2
- PIGA | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61238400; called by muse, mutect2, varscan2
- PIK3CG | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 570/688 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV63250959; called by muse, mutect2, varscan2
- PKD1L3 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV58663241; called by muse, mutect2, varscan2
- PKHD1L1 | c.8071C>T p.P2691S | Missense Mutation (SNP) | VAF 345/772 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs369491934; called by muse, mutect2, varscan2
- PLCH1 | c.143G>A p.R48Q (on ENST00000340059 / NM_001130960.2; = p.R60Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/277 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs374607347; called by muse, mutect2, varscan2
- PLCXD2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67342509; called by muse, mutect2
- PLEKHA1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs757265329, COSV64569787; called by muse, mutect2, varscan2
- PLPP1 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1327240900; called by muse, mutect2, varscan2
- PPP1R32 | c.225G>A p.R75= | Splice Region (SNP) | VAF 74/150 reads (49%) | catalogued as rs768129829; called by muse, mutect2, varscan2
- PPP6R3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761473539; called by muse, mutect2, varscan2
- PRMT5 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 79/210 reads (38%) | catalogued as rs1397689827, COSV53545184; called by muse, mutect2, varscan2
- PRR36 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.33); catalogued as rs1295820582; called by muse, mutect2, varscan2
- PSMB7 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as rs369427242; called by muse, mutect2, varscan2
- PTPN1 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1409849933; called by muse, mutect2, varscan2
- PUM1 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.094); catalogued as rs765212121; called by muse, mutect2, varscan2
- RAB22A | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as rs868506772, COSV54830987; called by muse, mutect2, varscan2
- RABGAP1L | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751561117, COSV52278381; called by muse, mutect2, varscan2
- RERE | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100557504; called by muse, mutect2
- RHOXF2 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 198/842 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs782413530; called by muse, mutect2, varscan2
- RP1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 320/642 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV55114526, COSV99609488; called by muse, mutect2, varscan2
- RPS6KA6 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 70/70 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53126477; called by muse, mutect2
- RUNX1T1 | c.1159G>A p.E387K (on ENST00000265814 / NM_001198628.1; = p.E360K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 726/1338 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV56147503; called by muse, mutect2, varscan2
- RXFP1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 115/179 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs267600062, COSV57054866; called by muse, mutect2, varscan2
- RYR3 | c.8019G>T p.E2673D (on ENST00000389232; = p.E2674D on NM_001036.6) | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV66810696; called by muse, mutect2, varscan2
- SATL1 | c.500G>A p.R167Q (on ENST00000395409; = p.R354Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs1324962730, COSV60577618; called by muse, mutect2, varscan2
- SCN10A | c.1972C>G p.L658V | Missense Mutation (SNP) | VAF 137/474 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV101479461; called by muse, mutect2, varscan2
- SETDB1 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs374101197; called by muse, mutect2, varscan2
- SIGLEC12 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 204/716 reads (28%) | catalogued as rs749952086, COSV52461771; called by muse, mutect2
- SLC22A24 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs765593659, COSV58223786; called by muse, mutect2, varscan2
- SLC44A3 | c.520C>T p.P174S (on ENST00000271227 / NM_001114106.3; = p.P126S on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54730476; called by muse, mutect2, varscan2
- SLC9C1 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59884871; called by muse, mutect2, varscan2
- SOX9 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs1033953308; called by muse, mutect2, varscan2
- SPAG17 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377326727; called by muse, mutect2, varscan2
- SPTLC2 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53640371; called by muse, mutect2, varscan2
- SREBF2 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 438/858 reads (51%) | catalogued as COSV63331105; called by muse, mutect2, varscan2
- ST18 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 69/541 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52486892; called by muse, mutect2, varscan2
- ST8SIA5 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 49/168 reads (29%) | PolyPhen probably damaging (1); catalogued as rs777525997; called by muse, mutect2, varscan2
- STYXL2 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs962263097; called by muse, mutect2, varscan2
- SUCO | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 62/275 reads (23%) | catalogued as COSV55266363; called by muse, mutect2, varscan2
- SYT16 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 223/457 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as rs766604821, COSV70856665; called by muse, mutect2, varscan2
- TDRD1 | c.3481C>T p.L1161F | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52596305, COSV99315196; called by muse, varscan2
- TERT | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 434/435 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs749827230; called by muse, mutect2, varscan2
- TEX44 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 832/834 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1380416171; called by muse, mutect2, varscan2
- TIAM1 | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.056); catalogued as rs752519456, COSV99732690; called by muse, mutect2, varscan2
- TIE1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1467879042, COSV65250257; called by muse, mutect2, varscan2
- TMEM132C | c.2908G>A p.D970N | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs560254297, COSV59416589; called by muse, mutect2, varscan2
- TMEM233 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs752467663, COSV70311768; called by muse, mutect2, varscan2
- TRANK1 | c.5234C>T p.S1745F | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs966252239; called by muse, mutect2, varscan2
- TRIM64B | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334125472; called by mutect2, varscan2
- TRIM71 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV67470710; called by muse, mutect2
- TRPC5 | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 227/227 reads (100%) | catalogued as COSV53289550; called by muse, mutect2, varscan2
- TTC23L | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 103/104 reads (99%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs371992268; called by muse, mutect2, varscan2
- TTN | c.8422G>A p.E2808K (on ENST00000591111; = p.E2762K on NM_003319.4) | Missense Mutation (SNP) | VAF 346/347 reads (100%) | PolyPhen benign (0.153); catalogued as COSV100628125, COSV60070729; called by muse, mutect2, varscan2
- UGT2A3 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV52360848; called by muse, mutect2
- UNC5A | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1158622068; called by muse, mutect2
- UNC80 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs1002766231; called by muse, mutect2, varscan2
- VN1R4 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV60804666, COSV60805487; called by muse, mutect2, varscan2
- ZFP41 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 206/518 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs772582387, COSV58085955; called by muse, mutect2, varscan2
- ZIM3 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 175/269 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.599); catalogued as COSV99517755; called by muse, mutect2, varscan2
- ZNF804B | c.897C>G p.N299K | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs989331135; called by muse, mutect2, varscan2
- ABCC4 | c.3074G>A p.W1025* | Nonsense Mutation (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- ABCC6 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC8 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ABCG8 | c.1491C>T p.I497= | Splice Region (SNP) | VAF 434/435 reads (100%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.3608dup p.L1203Ffs*7 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.16285C>T p.P5429S | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ANKRD9 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- AOC1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AP2A2 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- APCS | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- APOBEC4 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 313/448 reads (70%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQP1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- BCO2 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BICRA | c.3574C>G p.Q1192E | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- C10orf71 | c.4282G>A p.D1428N | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C1QTNF9B | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CES5A | c.128A>T p.K43M | Missense Mutation (SNP) | VAF 98/202 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CHD5 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CHD7 | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.168); called by muse, mutect2
- CHDH | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CNGA2 | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNGA3 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 341/342 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL11A2 | c.2686C>T p.P896S (on ENST00000341947 / NM_080680.3; = p.P789S on NM_080679.2) | Missense Mutation (SNP) | VAF 376/783 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL7A1 | c.6328C>T p.P2110S | Missense Mutation (SNP) | VAF 220/690 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CROCC | c.4573C>T p.R1525W | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSMD3 | c.5022G>A p.M1674I (on ENST00000297405 / NM_001363185.1; = p.M1570I on NM_052900.3) | Missense Mutation (SNP) | VAF 121/301 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CUL9 | c.5797C>T p.L1933F | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP2J2 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP46A1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH1 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- DDX11 | c.2123C>A p.P708H | Missense Mutation (SNP) | VAF 340/361 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DGKK | c.1857G>A p.M619I | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- DNAH12 | c.7855C>T p.Q2619* (on ENST00000351747; = p.Q3487* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- DPYD | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DRC3 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DVL1 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHBP1L1 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ENPP6 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EPHB4 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 399/508 reads (79%) | called by muse, mutect2, varscan2
- ERN1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM151B | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM184A | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAT4 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FBXL12 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FBXW8 | c.743C>T p.P248L (on ENST00000309909; = p.P286L on NM_012174.1) | Missense Mutation (SNP) | VAF 256/257 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FCSK | c.2876A>T p.N959I | Missense Mutation (SNP) | VAF 172/349 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FLNC | c.2189A>T p.Y730F | Missense Mutation (SNP) | VAF 179/1169 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMN2 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FOLR1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 217/443 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FPR2 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FREM2 | c.3717G>A p.M1239I | Missense Mutation (SNP) | VAF 252/532 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMPD2 | c.871T>C p.S291P | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- FUT1 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 331/490 reads (68%) | called by muse, mutect2, varscan2
- FYB2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GAGE10 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 68/1167 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLRA2 | c.830G>A p.W277* | Nonsense Mutation (SNP) | VAF 173/173 reads (100%) | called by muse, mutect2, varscan2
- GPT | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 564/1005 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- HBD | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 215/411 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- HLA-A | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 78/516 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- HTR2C | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 79/80 reads (99%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- HTR4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 101/101 reads (100%) | PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- IGHV3-64 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 147/341 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- IGHV4-61 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 182/564 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- IL37 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- INSRR | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- IQUB | c.1410+2T>C p.X470_splice | Splice Site (SNP) | VAF 62/414 reads (15%) | called by muse, mutect2, varscan2
- KCNA4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- KHDC3L | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 408/409 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KIF13A | c.4712C>T p.S1571F | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- KIF17 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 196/384 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KLK6 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 332/461 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2C | c.11419G>A p.D3807N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA1 | c.7249G>A p.G2417S | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MAP1S | c.2546C>G p.P849R | Missense Mutation (SNP) | VAF 112/158 reads (71%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.608); called by muse, mutect2
- MARCHF10 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 317/498 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARK3 | c.205A>C p.K69Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MEGF8 | c.740-1G>A p.X247_splice | Splice Site (SNP) | VAF 62/220 reads (28%) | called by muse, mutect2, varscan2
- METTL15 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- MIA3 | c.2404G>A p.G802R | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- MIPEP | c.796G>C p.A266P | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MRC2 | c.3742G>A p.G1248R | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MROH2B | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTUS2 | c.1446G>C p.E482D | Missense Mutation (SNP) | VAF 170/341 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.43163G>A p.G14388E | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MUC16 | c.19561del p.T6521Pfs*21 | Frame Shift Del (DEL) | VAF 48/132 reads (36%) | called by mutect2, pindel, varscan2
- MYH4 | c.586T>A p.F196I | Missense Mutation (SNP) | VAF 137/137 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NCAPD3 | c.2561T>G p.V854G | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NCOA6 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NHLRC3 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 117/275 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- NOL8 | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 168/169 reads (99%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN2 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ONECUT2 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 116/458 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- OR10R2 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 238/350 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR2AK2 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR2F2 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 186/582 reads (32%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- OR4F17 | c.280A>T p.I94L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by mutect2, varscan2
- OR52N1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OTOGL | c.961T>G p.C321G (on ENST00000547103; = p.C312G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PCDHGB4 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.15026G>A p.G5009E | Missense Mutation (SNP) | VAF 125/155 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX1 | c.6601C>T p.P2201S | Missense Mutation (SNP) | VAF 102/205 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNX2 | c.537C>A p.D179E | Missense Mutation (SNP) | VAF 108/134 reads (81%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCSK2 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2
- PHKA1 | c.2048A>C p.K683T | Missense Mutation (SNP) | VAF 194/195 reads (99%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIGA | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHH1 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHH1 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 400/545 reads (73%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEG | c.1087A>T p.K363* | Nonsense Mutation (SNP) | VAF 87/650 reads (13%) | called by muse, mutect2, varscan2
- POU2F3 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRB3 | c.902G>A p.R301K (on ENST00000381842; = p.R343K on NM_006249.5) | Missense Mutation (SNP) | VAF 77/77 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRDM9 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 297/298 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PRX | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 244/829 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRS | c.827T>G p.V276G | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD23A | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGAPA1 | c.4073C>T p.P1358L | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAPGEF4 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 426/426 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- RB1CC1 | c.1169C>G p.A390G | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- RCC2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RGS3 | c.1093C>T p.P365S (on ENST00000350696 / NM_001282923.2; = p.P253S on NM_017790.4) | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- RGS3 | c.1094C>T p.P365L (on ENST00000350696 / NM_001282923.2; = p.P253L on NM_017790.4) | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- RIMKLB | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- RIMS2 | c.4560+2T>G p.X1520_splice (on ENST00000666250 / NM_001348490.2; = p.X1091_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 39/268 reads (15%) | called by muse, mutect2, varscan2
- RPTN | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 136/503 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RYR2 | c.13258C>T p.Q4420* | Nonsense Mutation (SNP) | VAF 366/504 reads (73%) | called by muse, mutect2, varscan2
- SACS | c.7618C>T p.P2540S | Missense Mutation (SNP) | VAF 145/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SBF2 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SCN3A | c.5911G>A p.D1971N | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SH3TC2 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 207/446 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SIGLEC1 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SIGLEC8 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 306/432 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SIN3B | c.2378C>T p.S793F | Missense Mutation (SNP) | VAF 252/409 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- SIRT6 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 151/293 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC16A6 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SLC25A12 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC5A7 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SLFN13 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT tolerated (0.68); PolyPhen benign (0.287); called by mutect2, varscan2
- SPAM1 | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 75/494 reads (15%) | called by muse, mutect2, varscan2
- SRRM2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.505); called by muse, varscan2
- STARD13 | c.2152C>T p.P718S (on ENST00000336934 / NM_001243476.3; = p.P600S on NM_052851.3) | Missense Mutation (SNP) | VAF 281/622 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- STK32B | c.240C>A p.H80Q | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5 | c.2545+2T>C p.X849_splice (on ENST00000321680 / NM_001127715.2; = p.X813_splice on NM_139244.4) | Splice Site (SNP) | VAF 52/58 reads (90%) | called by muse, varscan2
- SYCP1 | c.148T>A p.F50I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- TBPL2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- TBX18 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 113/113 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD1 | c.3478T>C p.F1160L | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- TECPR1 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 70/410 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- TM9SF4 | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM106B | c.407_409del p.D136del | In Frame Del (DEL) | VAF 24/119 reads (20%) | called by pindel, varscan2
- TMPRSS7 | c.1645G>A p.D549N (on ENST00000452346; = p.D423N on NM_001042575.2) | Missense Mutation (SNP) | VAF 156/258 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFRSF17 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TNFSF8 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 82/82 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- TRAV6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TRIM46 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 81/362 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRIM49B | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 211/492 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- TSPAN2 | c.295_300del p.F99_A100del | In Frame Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- TTLL3 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 143/405 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBN2 | c.1622A>T p.Q541L | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UGT2B11 | c.497T>C p.I166T | Missense Mutation (SNP) | VAF 192/300 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- USH1C | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 156/316 reads (49%) | called by muse, mutect2, varscan2
- USH2A | c.6100G>A p.A2034T | Missense Mutation (SNP) | VAF 156/631 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VPS41 | c.2558A>G p.K853R | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VPS8 | c.2996T>C p.V999A (on ENST00000625842 / NM_001349294.1; = p.V997A on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- XYLT2 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 271/406 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ZDBF2 | c.1993G>C p.G665R | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); called by muse, mutect2
- ZDHHC8 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 159/298 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZNF225 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 165/250 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF229 | c.1420T>A p.S474T | Missense Mutation (SNP) | VAF 118/404 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF292 | c.890T>A p.L297H | Missense Mutation (SNP) | VAF 54/54 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF318 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 199/496 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF541 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 490/710 reads (69%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ZNF585A | c.1882C>T p.H628Y (on ENST00000292841 / NM_001288800.2; = p.H573Y on NM_152655.3) | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF606 | c.1432C>T p.H478Y | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF607 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 149/238 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ZNF672 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 226/310 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ZNF761 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 138/399 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ZNF835 | c.917A>C p.Y306S | Missense Mutation (SNP) | VAF 171/608 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACADS | c.345C>T p.I115= | Silent (SNP) | VAF 248/248 reads (100%) | called by muse, mutect2, varscan2
- AMOTL1 | c.2379C>T p.S793= | Silent (SNP) | VAF 228/443 reads (51%) | catalogued as rs764885723, COSV58570683; called by muse, mutect2, varscan2
- ANHX | c.937C>T p.L313= | Silent (SNP) | VAF 141/141 reads (100%) | catalogued as rs773361587; called by muse, mutect2, varscan2
- ANK2 | c.1671C>T p.S557= | Silent (SNP) | VAF 253/397 reads (64%) | called by muse, mutect2, varscan2
- AP2A2 | c.2106C>T p.S702= | Silent (SNP) | VAF 83/165 reads (50%) | catalogued as rs750115677, COSV104407661; called by muse, mutect2, varscan2
- APOE | c.36C>T p.F12= | Silent (SNP) | VAF 145/429 reads (34%) | catalogued as rs1381224336, COSV52986720; called by muse, mutect2, varscan2
- AQP1 | c.354C>T p.S118= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as rs1219391889, COSV61266462; called by muse, mutect2, varscan2
- ARAP2 | c.4713G>A p.G1571= | Silent (SNP) | VAF 103/153 reads (67%) | called by muse, mutect2, varscan2
- ARAP2 | c.1515G>A p.V505= | Silent (SNP) | VAF 60/97 reads (62%) | catalogued as rs779238668; called by muse, mutect2, varscan2
- ARHGEF16 | c.1326G>A p.Q442= | Silent (SNP) | VAF 97/246 reads (39%) | catalogued as COSV65683479; called by muse, mutect2, varscan2
- ARMC12 | c.891G>A p.L297= (on ENST00000373866 / NM_001286574.2; = p.L324= on NM_145028.5) | Silent (SNP) | VAF 193/430 reads (45%) | called by muse, mutect2, varscan2
- ASAH2 | c.1317C>T p.L439= | Silent (SNP) | VAF 352/353 reads (100%) | called by muse, mutect2, varscan2
- ATP9A | c.1578G>A p.L526= | Silent (SNP) | VAF 51/146 reads (35%) | called by muse, mutect2, varscan2
- BMT2 | c.498C>T p.I166= | Silent (SNP) | VAF 54/354 reads (15%) | called by muse, mutect2, varscan2
- BSN | c.8100C>T p.I2700= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs765632548, COSV56513718; called by muse, mutect2, varscan2
- C20orf85 | c.288G>A p.Q96= | Silent (SNP) | VAF 119/181 reads (66%) | called by muse, mutect2, varscan2
- C7 | c.315G>A p.G105= | Silent (SNP) | VAF 139/139 reads (100%) | catalogued as COSV57473062; called by muse, mutect2, varscan2
- C7orf26 | c.1206C>T p.P402= | Silent (SNP) | VAF 284/370 reads (77%) | catalogued as rs767179344; called by muse, mutect2, varscan2
- CACNA1B | c.1851C>T p.F617= | Silent (SNP) | VAF 191/191 reads (100%) | catalogued as rs1442216247, COSV99498015; called by muse, mutect2, varscan2
- CASQ1 | c.939C>T p.N313= | Silent (SNP) | VAF 168/263 reads (64%) | called by muse, mutect2, varscan2
- CBR3 | c.621C>T p.I207= | Silent (SNP) | VAF 120/375 reads (32%) | catalogued as rs1410571720; called by muse, mutect2, varscan2
- CCDC63 | c.1524C>A p.P508= | Silent (SNP) | VAF 74/75 reads (99%) | called by muse, mutect2, varscan2
- CCER1 | c.1038C>T p.V346= | Silent (SNP) | VAF 116/116 reads (100%) | called by muse, mutect2, varscan2
- CDK18 | c.507G>A p.G169= (on ENST00000506784 / NM_212503.3; = p.G139= on NM_002596.4) | Silent (SNP) | VAF 74/99 reads (75%) | catalogued as COSV63728067; called by muse, mutect2, varscan2
- CEP350 | c.2973G>T p.G991= | Silent (SNP) | VAF 293/389 reads (75%) | called by muse, mutect2, varscan2
- CIZ1 | c.1737C>T p.T579= | Silent (SNP) | VAF 74/75 reads (99%) | called by muse, mutect2, varscan2
- CNGB3 | c.2400T>A p.T800= | Silent (SNP) | VAF 33/293 reads (11%) | catalogued as rs1563711116; called by muse, mutect2, varscan2
- COL17A1 | c.1059T>C p.P353= | Silent (SNP) | VAF 167/361 reads (46%) | called by muse, mutect2, varscan2
- COL4A4 | c.1509C>T p.G503= | Silent (SNP) | VAF 591/592 reads (100%) | catalogued as rs759563620, COSV100307658, COSV100307968; called by muse, mutect2, varscan2
- CRTAC1 | c.1450C>T p.L484= | Silent (SNP) | VAF 181/182 reads (99%) | called by muse, mutect2, varscan2
- CUBN | c.5868C>T p.F1956= | Silent (SNP) | VAF 209/210 reads (100%) | called by muse, mutect2, varscan2
- CUL9 | c.5796C>T p.H1932= | Silent (SNP) | VAF 160/380 reads (42%) | called by muse, mutect2, varscan2
- DAAM2 | c.1743C>T p.L581= | Silent (SNP) | VAF 96/216 reads (44%) | called by muse, varscan2
- DAND5 | c.168C>T p.A56= | Silent (SNP) | VAF 114/163 reads (70%) | catalogued as rs1290364264; called by muse, mutect2, varscan2
- DCAF8L2 | c.792G>A p.L264= | Silent (SNP) | VAF 303/303 reads (100%) | catalogued as COSV70547931; called by muse, mutect2, varscan2
- DDC | c.192C>T p.I64= | Silent (SNP) | VAF 622/851 reads (73%) | called by muse, mutect2, varscan2
- DDX11 | c.2124C>A p.P708= | Silent (SNP) | VAF 339/361 reads (94%) | called by muse, mutect2, varscan2
- DDX24 | c.1305C>T p.N435= | Silent (SNP) | VAF 62/133 reads (47%) | called by muse, mutect2, varscan2
- DIPK1B | c.669C>G p.G223= | Silent (SNP) | VAF 391/391 reads (100%) | called by muse, mutect2, varscan2
- DMBX1 | c.606C>T p.D202= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs764711059; called by muse, mutect2
- DNAH8 | c.3837G>A p.Q1279= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs921357592; called by muse, mutect2, varscan2
- DNAH8 | c.13020G>A p.G4340= | Silent (SNP) | VAF 151/315 reads (48%) | catalogued as COSV59433677; called by muse, mutect2, varscan2
- EBNA1BP2 | c.384C>T p.V128= | Silent (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2
- EMILIN3 | c.754C>T p.L252= | Silent (SNP) | VAF 109/332 reads (33%) | catalogued as COSV60035222; called by muse, mutect2, varscan2
- EPN3 | c.630G>A p.E210= | Silent (SNP) | VAF 69/242 reads (29%) | called by muse, mutect2, varscan2
- EYS | c.6963C>T p.I2321= | Silent (SNP) | VAF 404/404 reads (100%) | called by muse, mutect2, varscan2
- FAM120A | c.1719C>T p.F573= | Silent (SNP) | VAF 194/194 reads (100%) | catalogued as rs758332800; called by muse, mutect2, varscan2
- FAM83C | c.342G>A p.G114= | Silent (SNP) | VAF 152/237 reads (64%) | catalogued as rs868633164; called by muse, mutect2, varscan2
- FAT4 | c.1896C>T p.F632= | Silent (SNP) | VAF 73/323 reads (23%) | catalogued as rs1374806485, COSV67897569; called by muse, mutect2, varscan2
- FAT4 | c.13209G>A p.P4403= | Silent (SNP) | VAF 188/312 reads (60%) | catalogued as rs763983959, COSV58678193, COSV58697379; called by muse, mutect2, varscan2
- FLG | c.11532G>A p.Q3844= | Silent (SNP) | VAF 247/1030 reads (24%) | called by muse, mutect2, varscan2
- FLNB | c.1920G>A p.T640= | Silent (SNP) | VAF 210/322 reads (65%) | catalogued as rs1176423483; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLT1 | c.3994C>T p.L1332= | Silent (SNP) | VAF 158/350 reads (45%) | called by muse, mutect2, varscan2
- GABRA6 | c.552C>T p.I184= | Silent (SNP) | VAF 63/63 reads (100%) | catalogued as COSV50877841, COSV99194252; called by muse, mutect2, varscan2
- GCC2 | c.1650A>G p.Q550= | Silent (SNP) | VAF 188/188 reads (100%) | called by muse, varscan2
- GDPD5 | c.534C>T p.I178= | Silent (SNP) | VAF 98/213 reads (46%) | catalogued as rs761322326, COSV61128578; called by muse, mutect2, varscan2
- GLYATL2 | c.549G>A p.G183= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as COSV54848903; called by muse, mutect2, varscan2
- GLYATL2 | c.96C>T p.F32= | Silent (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- GOLGA4 | c.3555C>T p.F1185= | Silent (SNP) | VAF 76/95 reads (80%) | called by muse, mutect2, varscan2
- GRXCR2 | c.525G>A p.V175= | Silent (SNP) | VAF 195/195 reads (100%) | called by muse, mutect2, varscan2
- HCFC1 | c.2538C>T p.L846= | Silent (SNP) | VAF 318/319 reads (100%) | called by muse, mutect2, varscan2
- HEATR5B | c.2007C>T p.V669= | Silent (SNP) | VAF 215/215 reads (100%) | catalogued as COSV51852780; called by muse, mutect2, varscan2
- HERC2 | c.2778T>C p.G926= | Silent (SNP) | VAF 77/291 reads (26%) | called by muse, mutect2, varscan2
- HIVEP2 | c.3927C>T p.P1309= | Silent (SNP) | VAF 105/107 reads (98%) | called by muse, mutect2, varscan2
- HMCN1 | c.6429C>T p.P2143= | Silent (SNP) | VAF 64/261 reads (25%) | catalogued as COSV99627470; called by muse, mutect2, varscan2
- HMCN2 | c.14061G>A p.V4687= | Silent (SNP) | VAF 186/187 reads (99%) | catalogued as rs190778300, COSV56739794; called by muse, mutect2, varscan2
- HNF4A | c.516C>T p.I172= | Silent (SNP) | VAF 193/616 reads (31%) | catalogued as rs773473316; called by muse, mutect2, varscan2
- HSPA6 | c.906C>T p.A302= | Silent (SNP) | VAF 160/853 reads (19%) | called by muse, mutect2, varscan2
- IGFBP4 | c.58C>T p.L20= | Silent (SNP) | VAF 251/252 reads (100%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.63C>T p.I21= | Silent (SNP) | VAF 256/499 reads (51%) | catalogued as rs575643371; called by muse, mutect2, varscan2
- IGHV3-13 | c.168C>T p.V56= | Silent (SNP) | VAF 158/309 reads (51%) | catalogued as rs782218813; called by muse, mutect2, varscan2
- IGHV6-1 | c.297G>A p.K99= | Silent (SNP) | VAF 61/123 reads (50%) | catalogued as rs782221974; called by muse, mutect2, varscan2
- IKBKE | c.1779G>A p.Q593= | Silent (SNP) | VAF 88/403 reads (22%) | called by muse, mutect2, varscan2
- IL1RAP | c.2058C>T p.I686= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as rs1293136748; called by muse, mutect2, varscan2
- IL22RA1 | c.888C>T p.A296= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2
- INAVA | c.237C>G p.L79= | Silent (SNP) | VAF 101/461 reads (22%) | catalogued as COSV66256435; called by muse, mutect2, varscan2
- INO80 | c.720C>T p.S240= | Silent (SNP) | VAF 111/368 reads (30%) | catalogued as rs866655826; called by muse, mutect2, varscan2
- ISL1 | c.342C>T p.L114= | Silent (SNP) | VAF 381/382 reads (100%) | catalogued as rs1407857849; called by muse, mutect2, varscan2
- JCHAIN | c.196C>T p.L66= | Silent (SNP) | VAF 88/143 reads (62%) | called by muse, mutect2, varscan2
- KCNQ2 | c.300C>T p.F100= | Silent (SNP) | VAF 103/361 reads (29%) | catalogued as rs1432645663; called by muse, mutect2, varscan2
- KDR | c.3276T>A p.G1092= | Silent (SNP) | VAF 96/331 reads (29%) | called by muse, mutect2, varscan2
- KHSRP | c.1656C>T p.P552= | Silent (SNP) | VAF 48/87 reads (55%) | called by muse, mutect2, varscan2
- KMT2B | c.2604C>T p.I868= | Silent (SNP) | VAF 87/125 reads (70%) | called by muse, mutect2, varscan2
- KRTAP4-2 | c.336G>A p.R112= | Silent (SNP) | VAF 249/252 reads (99%) | called by muse, mutect2, varscan2
- LAMA4 | c.1311C>T p.F437= (on ENST00000230538 / NM_001105206.3; = p.F430= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 143/143 reads (100%) | called by muse, mutect2, varscan2
- LAMB1 | c.3855G>A p.L1285= | Silent (SNP) | VAF 114/858 reads (13%) | catalogued as rs1002138075; called by muse, mutect2, varscan2
- MAPK8IP2 | c.2310C>T p.F770= | Silent (SNP) | VAF 191/398 reads (48%) | catalogued as rs752330110; called by muse, mutect2, varscan2
- MBD3L5 | c.9G>A p.E3= | Silent (SNP) | VAF 48/438 reads (11%) | called by muse, varscan2
- MUC16 | c.43164G>A p.G14388= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- MUC22 | c.2046C>T p.V682= | Silent (SNP) | VAF 156/305 reads (51%) | called by muse, mutect2, varscan2
- MYO7A | c.4689G>A p.A1563= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs759430551, COSV68686693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALADL2 | c.867G>A p.R289= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV69160857; called by muse, mutect2, varscan2
- NAV2 | c.1797C>T p.S599= (on ENST00000396087 / NM_001244963.2; = p.S576= on NM_145117.5) | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs754443258; called by muse, mutect2, varscan2
- NCOA6 | c.1224G>A p.Q408= | Silent (SNP) | VAF 66/194 reads (34%) | called by muse, mutect2, varscan2
- NDFIP2 | c.420A>G p.P140= | Silent (SNP) | VAF 124/247 reads (50%) | catalogued as rs1237888208; called by muse, mutect2, varscan2
- NEPRO | c.840T>G p.A280= | Silent (SNP) | VAF 114/174 reads (66%) | called by muse, mutect2, varscan2
- NLRP4 | c.234G>A p.K78= | Silent (SNP) | VAF 53/216 reads (25%) | catalogued as COSV56711305; called by muse, mutect2, varscan2
- NLRP8 | c.1059C>T p.T353= | Silent (SNP) | VAF 52/204 reads (25%) | catalogued as rs766749134, COSV52583708; called by muse, mutect2, varscan2
- NMNAT3 | c.138C>T p.I46= (on ENST00000296202 / NM_001320512.1; = p.I9= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/167 reads (66%) | catalogued as COSV56158240; called by muse, mutect2, varscan2
- NOD1 | c.429C>T p.F143= | Silent (SNP) | VAF 137/208 reads (66%) | catalogued as rs150469478; called by muse, mutect2
- NOP58 | c.27G>A p.V9= | Silent (SNP) | VAF 337/337 reads (100%) | catalogued as rs1468750836; called by muse, mutect2, varscan2
- NRP1 | c.2367C>T p.N789= | Silent (SNP) | VAF 108/108 reads (100%) | called by muse, mutect2, varscan2
- NUDT16 | c.39G>A p.L13= | Silent (SNP) | VAF 151/461 reads (33%) | called by muse, mutect2, varscan2
- OR10J3 | c.909G>A p.Q303= | Silent (SNP) | VAF 347/457 reads (76%) | catalogued as COSV59954356; called by muse, mutect2, varscan2
- OR2L3 | c.930G>A p.G310= | Silent (SNP) | VAF 123/168 reads (73%) | catalogued as COSV63454821, COSV63455867; called by muse, mutect2, varscan2
- OR2Y1 | c.696G>A p.G232= | Silent (SNP) | VAF 158/158 reads (100%) | catalogued as rs765581542; called by muse, mutect2, varscan2
- OR51G1 | c.453G>A p.V151= | Silent (SNP) | VAF 17/314 reads (5%) | called by muse, mutect2
- OR51I1 | c.327C>T p.F109= | Silent (SNP) | VAF 90/162 reads (56%) | called by muse, mutect2, varscan2
- OR56A3 | c.117C>T p.F39= | Silent (SNP) | VAF 115/236 reads (49%) | catalogued as rs267603043, COSV61568941; called by muse, mutect2, varscan2
- OR7G3 | c.249G>A p.V83= | Silent (SNP) | VAF 72/147 reads (49%) | catalogued as rs748190024; called by muse, mutect2, varscan2
- OXER1 | c.990G>A p.L330= | Silent (SNP) | VAF 381/381 reads (100%) | called by muse, mutect2, varscan2
- OXGR1 | c.180C>T p.F60= | Silent (SNP) | VAF 55/109 reads (50%) | called by muse, mutect2, varscan2
- PCDHB7 | c.528C>T p.A176= | Silent (SNP) | VAF 52/52 reads (100%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.609C>T p.S203= | Silent (SNP) | VAF 229/229 reads (100%) | called by muse, mutect2, varscan2
- PCSK5 | c.4968G>A p.G1656= | Silent (SNP) | VAF 89/89 reads (100%) | called by muse, mutect2, varscan2
- PGK1 | c.75C>T p.F25= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- PHLPP2 | c.1443C>T p.S481= | Silent (SNP) | VAF 160/314 reads (51%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7749C>T p.G2583= | Silent (SNP) | VAF 236/520 reads (45%) | called by muse, mutect2, varscan2
- PLAAT2 | c.438C>A p.A146= | Silent (SNP) | VAF 86/163 reads (53%) | called by muse, mutect2, varscan2
- PLCH1 | c.144G>A p.R48= (on ENST00000340059 / NM_001130960.2; = p.R60= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 177/278 reads (64%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.2859G>A p.E953= (on ENST00000394691; = p.E1009= on NM_001308147.2) | Silent (SNP) | VAF 144/294 reads (49%) | called by muse, mutect2, varscan2
- PODXL | c.225G>A p.L75= | Silent (SNP) | VAF 603/728 reads (83%) | called by muse, mutect2, varscan2
- POTEH | c.1398C>T p.F466= | Silent (SNP) | VAF 127/2028 reads (6%) | catalogued as rs1163052872, COSV58883567; called by muse, mutect2
- POU3F2 | c.1251G>A p.G417= | Silent (SNP) | VAF 144/144 reads (100%) | catalogued as rs761254912, COSV60408917; called by muse, mutect2, varscan2
- PRMT5 | c.1041C>T p.D347= | Silent (SNP) | VAF 77/207 reads (37%) | called by muse, mutect2, varscan2
- PROX1 | c.1941C>T p.V647= | Silent (SNP) | VAF 45/287 reads (16%) | called by muse, mutect2, varscan2
- PTCHD3 | c.1788C>T p.L596= | Silent (SNP) | VAF 144/144 reads (100%) | called by muse, mutect2, varscan2
- PTK2 | c.1968G>A p.T656= | Silent (SNP) | VAF 561/1065 reads (53%) | catalogued as rs776101894, COSV100569374; called by muse, mutect2, varscan2
- PTPRC | c.2673G>A p.Q891= | Silent (SNP) | VAF 168/737 reads (23%) | called by muse, mutect2, varscan2
- RASSF6 | c.336C>T p.F112= (on ENST00000342081 / NM_201431.2; = p.F80= on NM_177532.5) | Silent (SNP) | VAF 105/162 reads (65%) | called by muse, mutect2, varscan2
- RBM47 | c.705C>T p.I235= | Silent (SNP) | VAF 294/456 reads (64%) | catalogued as COSV55934527; called by muse, mutect2, varscan2
- RFPL3 | c.738G>A p.G246= (on ENST00000249007 / NM_001098535.1; = p.G217= on NM_006604.2) | Silent (SNP) | VAF 73/155 reads (47%) | called by muse, mutect2, varscan2
- RFPL4A | c.369G>A p.L123= | Silent (SNP) | VAF 66/578 reads (11%) | called by mutect2, varscan2
- RFPL4AL1 | c.369G>A p.L123= | Silent (SNP) | VAF 99/508 reads (19%) | called by muse, mutect2, varscan2
- RNF128 | c.630C>T p.F210= (on ENST00000255499 / NM_194463.2; = p.F184= on NM_024539.3) | Silent (SNP) | VAF 254/258 reads (98%) | catalogued as rs866543939, COSV55249071; called by mutect2, varscan2
- RP1 | c.3201A>G p.K1067= | Silent (SNP) | VAF 197/430 reads (46%) | called by muse, mutect2, varscan2
- RPL26L1 | c.15C>T p.P5= | Silent (SNP) | VAF 190/190 reads (100%) | catalogued as rs1314443385; called by muse, mutect2, varscan2
- RYR1 | c.5094G>A p.E1698= | Silent (SNP) | VAF 118/348 reads (34%) | called by muse, mutect2, varscan2
- SAMD4A | c.1899C>T p.I633= | Silent (SNP) | VAF 121/235 reads (51%) | called by muse, mutect2, varscan2
- SATL1 | c.60C>T p.V20= (on ENST00000395409; = p.V207= on NM_001012980.2) | Silent (SNP) | VAF 419/421 reads (100%) | catalogued as COSV60578461; called by muse, mutect2, varscan2
- SCN1A | c.3741G>A p.T1247= (on ENST00000303395 / NM_001202435.3; = p.T1236= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 190/191 reads (99%) | catalogued as rs200745708, COSV57684225; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDR9C7 | c.228C>T p.T76= | Silent (SNP) | VAF 251/251 reads (100%) | called by muse, mutect2, varscan2
- SEC24D | c.1668C>T p.V556= | Silent (SNP) | VAF 64/232 reads (28%) | catalogued as COSV54882028; called by muse, mutect2, varscan2
- SELP | c.1242C>T p.F414= | Silent (SNP) | VAF 175/260 reads (67%) | called by muse, mutect2, varscan2
- SGSM1 | c.294C>T p.I98= | Silent (SNP) | VAF 120/232 reads (52%) | catalogued as rs373806756, COSV68514025; called by muse, mutect2, varscan2
- SIRT6 | c.822C>T p.P274= | Silent (SNP) | VAF 145/286 reads (51%) | catalogued as rs144184492; called by muse, mutect2, varscan2
- SLC13A1 | c.330G>A p.L110= | Silent (SNP) | VAF 71/494 reads (14%) | catalogued as rs1348916225, COSV52010095; called by muse, mutect2, varscan2
- SLC30A8 | c.186G>A p.K62= | Silent (SNP) | VAF 595/1049 reads (57%) | catalogued as rs369417167; called by muse, mutect2, varscan2
- SLC7A4 | c.975C>T p.S325= | Silent (SNP) | VAF 67/135 reads (50%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.201C>T p.I67= | Silent (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.1278C>T p.L426= | Silent (SNP) | VAF 224/379 reads (59%) | catalogued as rs146811388; called by muse, mutect2, varscan2
- SMC1B | c.273G>A p.E91= | Silent (SNP) | VAF 123/294 reads (42%) | catalogued as COSV61581930; called by muse, mutect2, varscan2
- SNX13 | c.2733C>T p.F911= | Silent (SNP) | VAF 112/259 reads (43%) | catalogued as rs749143658; called by muse, mutect2, varscan2
- SOHLH2 | c.762G>A p.E254= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as rs752689317; called by muse, mutect2, varscan2
- SPO11 | c.462C>T p.I154= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- SPPL2B | c.1326C>T p.S442= | Silent (SNP) | VAF 72/176 reads (41%) | catalogued as rs751747478, COSV101194650; called by muse, mutect2, varscan2
- SPTBN2 | c.6534C>T p.P2178= | Silent (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- SUGP1 | c.969C>T p.S323= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- SUMF1 | c.735C>T p.P245= | Silent (SNP) | VAF 114/358 reads (32%) | called by muse, mutect2, varscan2
- SYCP1 | c.147A>G p.P49= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- TBC1D26 | c.568C>T p.L190= | Silent (SNP) | VAF 238/238 reads (100%) | called by muse, mutect2, varscan2
- TC2N | c.21G>A p.K7= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100563039; called by muse, mutect2, varscan2
- TECPR1 | c.753G>T p.G251= | Silent (SNP) | VAF 69/410 reads (17%) | called by muse, mutect2, varscan2
- TERT | c.2205C>T p.P735= | Silent (SNP) | VAF 441/443 reads (100%) | called by muse, mutect2, varscan2
- TIAL1 | c.1068C>T p.P356= | Silent (SNP) | VAF 207/207 reads (100%) | catalogued as COSV64844114; called by muse, mutect2, varscan2
- TKTL2 | c.843G>A p.Q281= | Silent (SNP) | VAF 54/86 reads (63%) | catalogued as COSV54920812; called by muse, mutect2, varscan2
- TMC3 | c.765G>A p.T255= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as rs375067089; called by muse, mutect2, varscan2
- TMEM259 | c.1680C>T p.S560= | Silent (SNP) | VAF 160/316 reads (51%) | catalogued as rs907176892; called by muse, mutect2, varscan2
- TMPRSS9 | c.369C>T p.F123= | Silent (SNP) | VAF 118/233 reads (51%) | catalogued as COSV104409063; called by muse, mutect2, varscan2
- TNRC6A | c.5883C>T p.S1961= | Silent (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- TRANK1 | c.5235C>T p.S1745= | Silent (SNP) | VAF 66/225 reads (29%) | called by muse, mutect2, varscan2
- TRPC4 | c.606C>T p.A202= | Silent (SNP) | VAF 147/301 reads (49%) | called by muse, mutect2, varscan2
- TUB | c.1371C>T p.I457= (on ENST00000299506 / NM_177972.3; = p.I512= on NM_003320.4) | Silent (SNP) | VAF 66/132 reads (50%) | catalogued as COSV55108103; called by muse, mutect2, varscan2
- UBA52 | c.168C>T p.L56= | Silent (SNP) | VAF 137/202 reads (68%) | called by muse, mutect2, varscan2
- UBE4A | c.42C>T p.P14= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs1308445774; called by muse, varscan2
- WNK4 | c.2283C>T p.T761= | Silent (SNP) | VAF 123/123 reads (100%) | called by muse, mutect2, varscan2
- XIRP2 | c.7344G>T p.V2448= (on ENST00000628543; = p.V2623= on NM_152381.6) | Silent (SNP) | VAF 356/356 reads (100%) | called by muse, mutect2, varscan2
- YLPM1 | c.2655C>T p.S885= | Silent (SNP) | VAF 143/298 reads (48%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.540C>T p.A180= | Silent (SNP) | VAF 155/292 reads (53%) | catalogued as rs531244215; called by muse, mutect2, varscan2
- ZFHX4 | c.9042G>A p.V3014= | Silent (SNP) | VAF 188/469 reads (40%) | catalogued as COSV50490894; called by muse, mutect2, varscan2
- ZFP41 | c.372C>T p.F124= | Silent (SNP) | VAF 210/520 reads (40%) | called by muse, mutect2, varscan2
- ZFPM1 | c.546G>A p.A182= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs148071393; called by muse, mutect2, varscan2
- ZNF620 | c.183C>T p.S61= | Silent (SNP) | VAF 245/368 reads (67%) | called by muse, mutect2, varscan2
- AC048338.2 | c.*64C>T | 3'UTR (SNP) | VAF 140/140 reads (100%) | called by muse, mutect2, varscan2
- ACAT1 | c.334+20G>A | Intron (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- ACOT7 | c.174-10727C>G | Intron (SNP) | VAF 81/169 reads (48%) | catalogued as rs773242934; called by muse, mutect2, varscan2
- ADTRP | c.*57C>T | 3'UTR (SNP) | VAF 71/172 reads (41%) | catalogued as rs201125395; called by muse, varscan2
- AFF3 | chr2:100105887 C>T | 5'Flank (SNP) | VAF 538/540 reads (100%) | called by muse, mutect2, varscan2
- ATM | c.4909+10T>G | Intron (SNP) | VAF 107/242 reads (44%) | called by muse, mutect2, varscan2
- ATP9B | c.3013-241G>A | Intron (SNP) | VAF 97/145 reads (67%) | catalogued as rs531234258; called by muse, mutect2, varscan2
- C3 | c.3647-10T>A | Intron (SNP) | VAF 128/268 reads (48%) | called by muse, mutect2, varscan2
- C8orf34 | c.1106-14745G>T | Intron (SNP) | VAF 109/227 reads (48%) | called by muse, mutect2, varscan2
- CACNG4 | c.*1004C>T | 3'UTR (SNP) | VAF 67/183 reads (37%) | called by muse, mutect2, varscan2
- CCDC148 | c.26-7460G>A | Intron (SNP) | VAF 103/103 reads (100%) | called by muse, mutect2, varscan2
- CCDC162P | n.3124G>A | RNA (SNP) | VAF 48/48 reads (100%) | called by muse, mutect2, varscan2
- CEACAM16 | c.-10G>A | 5'UTR (SNP) | VAF 132/398 reads (33%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.257G>A | RNA (SNP) | VAF 395/395 reads (100%) | called by muse, mutect2, varscan2
- CNGB1 | c.-8-27G>A | Intron (SNP) | VAF 87/196 reads (44%) | catalogued as rs761143910, COSV51906724; called by muse, mutect2, varscan2
- CNGB1 | c.-8-28G>A | Intron (SNP) | VAF 87/194 reads (45%) | called by muse, mutect2, varscan2
- COQ7 | c.-36C>T | 5'UTR (SNP) | VAF 74/175 reads (42%) | catalogued as rs776108097; called by muse, mutect2, varscan2
- COQ8A | c.853+51G>A | Intron (SNP) | VAF 40/172 reads (23%) | catalogued as rs1269450983; called by muse, mutect2, varscan2
- CRYL1 | c.633+23C>T | Intron (SNP) | VAF 192/412 reads (47%) | called by muse, mutect2, varscan2
- CTSA | chr20:45891284 G>A | 5'Flank (SNP) | VAF 166/246 reads (67%) | called by muse, mutect2, varscan2
- DLL4 | c.*39G>A | 3'UTR (SNP) | VAF 35/60 reads (58%) | called by muse, mutect2, varscan2
- EMBP1 | n.1074G>A | RNA (SNP) | VAF 28/66 reads (42%) | catalogued as rs782554238; called by muse, mutect2, varscan2
- EPB41L1 | c.1669-1774G>A | Intron (SNP) | VAF 95/286 reads (33%) | catalogued as rs1329997943, COSV52434878; called by muse, mutect2, varscan2
- EVPL | c.1537+19G>A | Intron (SNP) | VAF 144/274 reads (53%) | called by muse, varscan2
- EVPL | c.1537+18G>A | Intron (SNP) | VAF 140/274 reads (51%) | called by muse, varscan2
- EVPL | c.1537+17G>A | Intron (SNP) | VAF 143/281 reads (51%) | catalogued as rs1237012360; called by muse, varscan2
- FAM90A27P | n.549G>A | RNA (SNP) | VAF 33/156 reads (21%) | catalogued as rs1351075937; called by muse, mutect2, varscan2
- FBXL19 | c.37-52C>T | Intron (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- GBP3 | c.429-128C>T | Intron (SNP) | VAF 71/157 reads (45%) | called by muse, mutect2, varscan2
- GGA3 | c.*799C>T | 3'UTR (SNP) | VAF 88/332 reads (27%) | catalogued as rs1463284419; called by muse, mutect2, varscan2
- HACD1 | c.257+1209C>T | Intron (SNP) | VAF 87/87 reads (100%) | catalogued as rs533870354; called by muse, mutect2, varscan2
- IGHV3-74 | c.-9G>A | 5'UTR (SNP) | VAF 121/226 reads (54%) | catalogued as rs533703945; called by muse, mutect2, varscan2
- IQCE | c.394+476C>T | Intron (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- KCNE3 | c.*8G>A | 3'UTR (SNP) | VAF 95/232 reads (41%) | catalogued as COSV100035500; called by muse, mutect2, varscan2
- KDM4B | c.1116-443C>A | Intron (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.42-30C>T | Intron (SNP) | VAF 53/161 reads (33%) | catalogued as rs1189909921, COSV55596512; called by muse, mutect2, varscan2
- LIN52 | c.-41C>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs753463538; called by muse, varscan2
- LINC00692 | n.752C>T | RNA (SNP) | VAF 131/212 reads (62%) | catalogued as rs761137315; called by muse, mutect2, varscan2
- LINC01587 | n.342-17C>T | Intron (SNP) | VAF 65/90 reads (72%) | called by muse, mutect2, varscan2
- LINC01600 | n.705C>T | RNA (SNP) | VAF 100/169 reads (59%) | catalogued as rs780444821; called by muse, mutect2
- LINC01630 | n.219+73181G>A | Intron (SNP) | VAF 73/259 reads (28%) | catalogued as rs1304327837; called by muse, mutect2, varscan2
- LINC02873 | n.229C>T | RNA (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- MGAM | c.4618+5592C>T | Intron (SNP) | VAF 636/662 reads (96%) | called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109969 C>T | 5'Flank (SNP) | VAF 239/468 reads (51%) | called by muse, mutect2, varscan2
- MLIP | c.613-11706C>T | Intron (SNP) | VAF 304/699 reads (43%) | called by muse, mutect2, varscan2
- MUC5B | c.*222G>A | 3'UTR (SNP) | VAF 22/119 reads (18%) | catalogued as rs1461612644; called by muse, mutect2, varscan2
- MYCT1 | c.*533G>A | 3'UTR (SNP) | VAF 43/44 reads (98%) | called by muse, mutect2, varscan2
- NCALD | c.*616_*627del | 3'UTR (DEL) | VAF 51/286 reads (18%) | called by mutect2, pindel, varscan2
- NEBL | c.-32T>C | 5'UTR (SNP) | VAF 167/167 reads (100%) | called by muse, mutect2, varscan2
- NLRP5 | c.566-22G>A | Intron (SNP) | VAF 68/202 reads (34%) | catalogued as rs765414221; called by muse, mutect2, varscan2
- NOVA1 | c.519+39G>A | Intron (SNP) | VAF 34/94 reads (36%) | catalogued as rs373691624; called by muse, mutect2, varscan2
- NXF5 | n.393G>A | RNA (SNP) | VAF 90/90 reads (100%) | catalogued as COSV53793767; called by muse, mutect2, varscan2
- OR3A4P | n.612C>T | RNA (SNP) | VAF 268/268 reads (100%) | called by muse, mutect2, varscan2
- PARD3 | c.2227+1559A>T | Intron (SNP) | VAF 74/74 reads (100%) | called by muse, mutect2, varscan2
- PMPCA | c.1263+92C>T | Intron (SNP) | VAF 117/118 reads (99%) | catalogued as rs1419652990; called by muse, mutect2, varscan2
- PPP5D1 | n.340G>A | RNA (SNP) | VAF 68/241 reads (28%) | catalogued as rs774190059; called by muse, mutect2, varscan2
- PRAM1 | c.1975+30G>A | Intron (SNP) | VAF 97/178 reads (54%) | catalogued as rs537383254; called by muse, mutect2, varscan2
- PRKACB | c.47-3375C>T | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as COSV65761451; called by muse, mutect2, varscan2
- RALGAPA2 | c.1005+54G>A | Intron (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-666C>T | Intron (SNP) | VAF 137/279 reads (49%) | called by muse, mutect2, varscan2
- RPS26P15 | n.117C>G | RNA (SNP) | VAF 203/451 reads (45%) | called by muse, mutect2, varscan2
- RTN1 | c.1766-2663G>A | Intron (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
- SATB2 | c.347-15962G>A | Intron (SNP) | VAF 175/175 reads (100%) | catalogued as rs751691388; called by muse, mutect2, varscan2
- SLC22A23 | c.1703+90G>A | Intron (SNP) | VAF 75/269 reads (28%) | catalogued as rs1441497906; called by muse, mutect2, varscan2
- SLC25A48-AS1 | n.76G>A | RNA (SNP) | VAF 136/136 reads (100%) | catalogued as rs1406868478; called by muse, mutect2, varscan2
- SLC2A11 | c.1086+24G>A | Intron (SNP) | VAF 70/162 reads (43%) | catalogued as rs1359569053; called by muse, mutect2, varscan2
- SNORD116-26 | n.65C>T | RNA (SNP) | VAF 136/230 reads (59%) | catalogued as rs866386982; called by muse, mutect2, varscan2
- SRRM2 | c.657-14C>T | Intron (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- SRRM2-AS1 | n.547C>T | RNA (SNP) | VAF 156/302 reads (52%) | called by muse, mutect2, varscan2
- SULF1 | c.*417C>T | 3'UTR (SNP) | VAF 370/710 reads (52%) | called by muse, mutect2, varscan2
- SVIL2P | n.1952C>T | RNA (SNP) | VAF 225/225 reads (100%) | catalogued as rs1426474978; called by muse, mutect2, varscan2
- TLE6 | c.703-18G>A | Intron (SNP) | VAF 60/118 reads (51%) | catalogued as rs1228448857; called by muse, mutect2, varscan2
- TMC1 | c.1567-51G>A | Intron (SNP) | VAF 127/127 reads (100%) | called by muse, mutect2, varscan2
- TP53AIP1 | c.141+128C>T | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- TRNAU1AP | chr1:28579814 C>T | 3'Flank (SNP) | VAF 64/152 reads (42%) | catalogued as rs773190179; called by muse, mutect2, varscan2
- TTN | c.10360+3013G>A | Intron (SNP) | VAF 173/174 reads (99%) | catalogued as rs1042508167, COSV60033198; called by muse, mutect2, varscan2
- UNKL | c.1585+67G>A | Intron (SNP) | VAF 47/103 reads (46%) | catalogued as rs1191081581; called by muse, mutect2, varscan2
- USH1C | c.1285-7640C>T | Intron (SNP) | VAF 43/87 reads (49%) | catalogued as rs1393936941; called by muse, mutect2, varscan2
- WDR86 | c.163+136G>A | Intron (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- ZNF274 | c.-31C>T | 5'UTR (SNP) | VAF 49/154 reads (32%) | catalogued as rs1439849960; called by muse, mutect2, varscan2
- ZNF812P | n.1437C>T | RNA (SNP) | VAF 58/119 reads (49%) | catalogued as rs576821063; called by muse, mutect2, varscan2
- ZNF812P | n.1236G>A | RNA (SNP) | VAF 67/139 reads (48%) | catalogued as rs1251548375; called by muse, mutect2, varscan2
- ZNF823 | c.-14C>T | 5'UTR (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
